Somatic mutation profile of tumor specimen TCGA-N8-A56S-01A (aliquot TCGA-N8-A56S-01A-11D-A28R-08) from TCGA case TCGA-N8-A56S, project TCGA-UCS (Uterine Carcinosarcoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Mullerian mixed tumor; Tissue or organ of origin: Endometrium; FIGO stage: Stage IB; Age at diagnosis: 75.3 years (27,519 days).
Specimen TCGA-N8-A56S-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 40aea5ba-fc78-4dd0-8eb2-beff6b73148a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-N8-A56S-10A (Blood Derived Normal), aliquot TCGA-N8-A56S-10A-01D-A28U-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ae0e1d22-5e1a-413e-840d-ab9f5cc7b1d9

The open-access MAF lists 54 somatic variants for this specimen: 40 protein-altering or splice-affecting, 14 silent.
By variant classification: Missense Mutation 33, Silent 14, Frame Shift Del 3, Nonsense Mutation 2, Frame Shift Ins 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NHS | c.742C>T p.R248* | Nonsense Mutation (SNP) | VAF 35/102 reads (34%) | catalogued as rs1569310232, CM085588; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.298C>T p.Q100* | Nonsense Mutation (SNP) | VAF 73/97 reads (75%) | catalogued as rs1567555994, CM156961, COSV52702138, COSV53867973; ClinVar: pathogenic; called by muse, mutect2, varscan2
- AKR1B15 | c.515C>A p.A172D | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.435); catalogued as COSV71152652; called by muse, mutect2
- ASB13 | c.232G>A p.V78M | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs775464852; called by muse, mutect2
- CAMK2B | c.1399G>A p.E467K | Missense Mutation (SNP) | VAF 17/50 reads (34%) | SIFT tolerated, low confidence (0.64); PolyPhen benign (0.007); catalogued as rs374476287; called by muse, mutect2, varscan2
- CARD11 | c.2918G>A p.R973H | Missense Mutation (SNP) | VAF 53/128 reads (41%) | SIFT tolerated (0.08); PolyPhen benign (0.011); catalogued as rs141681466, COSV67796624; called by muse, mutect2, varscan2
- CHD7 | c.7958G>A p.R2653Q | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.992); catalogued as rs747082615, CM130249, COSV71108859; called by muse, mutect2, varscan2
- DAB1 | c.658del p.Y220Ifs*21 | Frame Shift Del (DEL) | VAF 40/88 reads (45%) | catalogued as COSV59723547; called by mutect2, pindel, varscan2
- ERMARD | c.1706G>A p.R569H | Missense Mutation (SNP) | VAF 22/55 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as rs774361460, COSV64648287; called by muse, mutect2, varscan2
- FAM222A | c.902G>A p.R301H | Missense Mutation (SNP) | VAF 7/14 reads (50%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.799); catalogued as rs200880090, COSV62723544; called by muse, mutect2, varscan2
- FAM71B | c.1391C>T p.A464V | Missense Mutation (SNP) | VAF 95/171 reads (56%) | SIFT deleterious (0.04); PolyPhen benign (0.02); catalogued as rs201677910, COSV57228913; called by muse, mutect2, varscan2
- GLIS2 | c.421dup p.A141Gfs*36 | Frame Shift Ins (INS) | VAF 30/86 reads (35%) | catalogued as rs770844816; called by mutect2, varscan2
- OGDHL | c.1144C>T p.R382C | Missense Mutation (SNP) | VAF 47/127 reads (37%) | SIFT tolerated (0.25); PolyPhen benign (0.075); catalogued as rs750135745; called by muse, mutect2, varscan2
- PCDHA4 | c.1543G>A p.G515S | Missense Mutation (SNP) | VAF 129/225 reads (57%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs1554124735, COSV63540276; called by muse, mutect2, varscan2
- STX3 | c.451C>T p.R151W | Missense Mutation (SNP) | VAF 17/57 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs767164155, COSV100275444; called by muse, mutect2, varscan2
- ZRANB1 | c.1799G>A p.R600Q | Missense Mutation (SNP) | VAF 24/68 reads (35%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.543); catalogued as rs752138326; called by muse, mutect2, varscan2
- ASB9 | c.180G>T p.W60C | Missense Mutation (SNP) | VAF 5/133 reads (4%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.796); called by muse, mutect2
- ASB9 | c.179G>T p.W60L | Missense Mutation (SNP) | VAF 5/131 reads (4%) | SIFT tolerated (0.32); PolyPhen benign (0.071); called by muse, mutect2
- CAD | c.2096G>T p.G699V | Missense Mutation (SNP) | VAF 37/82 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.212); called by muse, mutect2, varscan2
- CDHR2 | c.3169A>G p.K1057E | Missense Mutation (SNP) | VAF 16/64 reads (25%) | SIFT tolerated (0.11); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- CSF2RB | c.700T>C p.C234R | Missense Mutation (SNP) | VAF 18/38 reads (47%) | SIFT tolerated (0.77); PolyPhen benign (0); called by muse, mutect2, varscan2
- DUOX2 | c.3401C>T p.A1134V | Missense Mutation (SNP) | VAF 41/108 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- GCC2 | c.2030C>G p.S677C | Missense Mutation (SNP) | VAF 57/158 reads (36%) | SIFT tolerated (0.16); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- LARGE2 | c.1068C>A p.F356L | Missense Mutation (SNP) | VAF 36/41 reads (88%) | SIFT tolerated (0.07); PolyPhen benign (0.347); called by muse, mutect2, varscan2
- LPIN3 | c.1367A>T p.K456I | Missense Mutation (SNP) | VAF 21/689 reads (3%) | SIFT deleterious (0); PolyPhen benign (0.025); called by muse, mutect2
- LPP | c.1040C>G p.P347R | Missense Mutation (SNP) | VAF 34/92 reads (37%) | SIFT tolerated (0.11); PolyPhen benign (0.075); called by muse, mutect2, varscan2
- MAGEB1 | c.82G>T p.A28S | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.883); called by mutect2, varscan2
- MAP3K1 | c.3607_3617del p.P1203Sfs*5 | Frame Shift Del (DEL) | VAF 23/51 reads (45%) | called by mutect2, pindel, varscan2
- MPV17 | c.97A>G p.I33V | Missense Mutation (SNP) | VAF 55/126 reads (44%) | SIFT tolerated (0.13); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- PEX14 | c.298A>G p.S100G | Missense Mutation (SNP) | VAF 17/95 reads (18%) | SIFT tolerated (0.13); PolyPhen benign (0.138); called by muse, mutect2, varscan2
- POLR2A | c.5570C>T p.S1857F | Missense Mutation (SNP) | VAF 105/266 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.683); called by muse, mutect2, varscan2
- PRAMEF10 | c.1390C>T p.P464S | Missense Mutation (SNP) | VAF 41/50 reads (82%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PRRC2A | c.2684G>A p.G895E | Missense Mutation (SNP) | VAF 21/52 reads (40%) | SIFT tolerated (0.94); PolyPhen probably damaging (0.928); called by muse, mutect2, varscan2
- RFC1 | c.2167_2168del p.D723Wfs*6 (on ENST00000381897 / NM_001363496.2; = p.D722Wfs*6 on NM_002913.5 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 15/46 reads (33%) | called by mutect2, pindel, varscan2
- RREB1 | c.1021G>A p.A341T | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT tolerated (0.38); PolyPhen benign (0); called by muse, mutect2
- RSPRY1 | c.152G>A p.G51E | Missense Mutation (SNP) | VAF 97/205 reads (47%) | SIFT tolerated (0.28); PolyPhen benign (0.068); called by muse, mutect2, varscan2
- SLITRK2 | c.2294A>G p.E765G | Missense Mutation (SNP) | VAF 21/307 reads (7%) | SIFT tolerated (0.23); PolyPhen benign (0.001); called by muse, mutect2
- SRPK3 | c.1607_1612del p.T536_F538delinsI | In Frame Del (DEL) | VAF 49/147 reads (33%) | called by mutect2, pindel, varscan2
- ZER1 | c.697G>T p.D233Y | Missense Mutation (SNP) | VAF 12/15 reads (80%) | SIFT tolerated (0.99); PolyPhen possibly damaging (0.543); called by muse, mutect2, varscan2
- ZSWIM4 | c.2155T>C p.F719L | Missense Mutation (SNP) | VAF 35/46 reads (76%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ANO2 | c.102C>T p.L34= (on ENST00000356134 / NM_001278597.3; = p.L38= on NM_001278596.3) | Silent (SNP) | VAF 7/14 reads (50%) | called by muse, mutect2, varscan2
- BPTF | c.5814C>T p.S1938= | Silent (SNP) | VAF 42/57 reads (74%) | catalogued as rs758887059, COSV100075259; called by muse, mutect2, varscan2
- CLCN5 | c.486G>A p.A162= | Silent (SNP) | VAF 22/67 reads (33%) | catalogued as rs140312372; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GPR173 | c.39C>T p.G13= | Silent (SNP) | VAF 3/40 reads (8%) | catalogued as rs1181198643; called by muse, mutect2
- HGS | c.159C>T p.V53= | Silent (SNP) | VAF 70/83 reads (84%) | catalogued as rs998053974; called by muse, mutect2, varscan2
- HOXA13 | c.1140C>T p.V380= | Silent (SNP) | VAF 71/182 reads (39%) | catalogued as COSV56083713; called by muse, mutect2, varscan2
- LAMA5 | c.10554G>T p.L3518= | Silent (SNP) | VAF 23/98 reads (23%) | catalogued as COSV53354106; called by muse, mutect2, varscan2
- NBEAL2 | c.8190G>A p.K2730= | Silent (SNP) | VAF 6/15 reads (40%) | catalogued as rs1454063645; called by muse, mutect2, varscan2
- NID2 | c.786C>A p.I262= | Silent (SNP) | VAF 26/30 reads (87%) | catalogued as COSV53496743; called by muse, mutect2, varscan2
- NNT | c.2688A>C p.S896= | Silent (SNP) | VAF 23/70 reads (33%) | called by muse, mutect2, varscan2
- NWD1 | c.2016C>T p.S672= | Silent (SNP) | VAF 14/55 reads (25%) | catalogued as rs544074252; called by muse, mutect2, varscan2
- PRSS35 | c.1218C>T p.N406= | Silent (SNP) | VAF 22/49 reads (45%) | catalogued as rs370535612; called by muse, mutect2, varscan2
- TRPV4 | c.1173G>A p.R391= | Silent (SNP) | VAF 30/76 reads (39%) | called by muse, mutect2, varscan2
- VWF | c.6669C>T p.N2223= | Silent (SNP) | VAF 24/53 reads (45%) | catalogued as rs149847513; called by muse, mutect2, varscan2
